Gene-level copy-number profile of tumor specimen ALCH-B1P4-TTP1-A from ALCHEMIST case ALCH-B1P4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.6 years (24,309 days).
Specimen ALCH-B1P4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c43807f6-93c1-47e1-b7c5-16a3e65ee5e7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1P4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/56edee91-9f42-4a5c-90a1-5b7a037a0607

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 81; copy number 1: 32,699; copy number 2: 22,801; copy number 3: 2,705; copy number 4: 36; copy number 5: 14; copy number 6: 38; copy number 8: 12; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:236,072,295–236,072,556, 1 gene (within-gene range 0–1): RN7SL204P.
- chr4:8,981,436–8,982,360, 1 gene: AC073648.3.
- chr4:164,877,178–165,060,554, 20 genes: APELA, TRIM60P14, AC106872.3, AC106872.12, FAM218BP, AC106872.10, AC106872.5, NACA3P, AC106872.1, TRIM61, FAM218A, AC106872.4, AC106872.9, AC106872.8, AC106872.2, TRIM60, AC106872.11, AC106872.7, AC106872.6, TRIM75P.
- chr5:160,187,367–160,370,641, 7 genes (within-gene range 0–1): FABP6, FABP6-AS1, AC112191.1, CCNJL, AC112191.2, AC112191.3, C1QTNF2.
- chr6:73,368,555–73,417,566, 5 genes (within-gene range 0–1): OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43.
- chr7:102,456,238–102,473,168, 4 genes (within-gene range 0–2): ALKBH4, LRWD1, MIR5090, MIR4467.
- chr7:140,435,316–140,435,787, 1 gene: AC069335.1.
- chr7:140,609,847–140,609,955, 1 gene (within-gene range 0–1): Y_RNA.
- chr8:12,095,176–12,099,536, 1 gene: DEFB108D.
- chr8:12,115,767–12,182,719, 7 genes (within-gene range 0–3): FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr10:132,181,225–132,185,962, 1 gene (within-gene range 0–1): AL512622.1.
- chr11:70,467,856–71,252,577, 10 genes (within-gene range 0–1): SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:76,186,325–76,216,025, 3 genes: WNT11, AP000785.1, LINC02761.
- chr13:112,052,078–112,108,015, 5 genes: AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404.
- chr14:18,562,928–18,588,315, 2 genes (within-gene range 0–1): CR383656.13, CR383656.9.
- chr15:20,344,736–20,359,166, 1 gene: AC026495.1.
- chr16:58,665,109–58,734,342, 3 genes (within-gene range 0–1): SLC38A7, AC012183.1, GOT2.
- chr16:58,744,251–58,777,563, 3 genes (within-gene range 0–1): RNU6-1155P, RN7SL143P, GEMIN8P2.
- chr16:87,739,771–87,747,706, 1 gene (within-gene range 0–1): AC010536.2.
- chr17:4,364,164–4,364,453, 1 gene (within-gene range 0–1): RN7SL774P.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 2,805 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,230,030–12,512,047, 2 genes, copy number 3: VPS13D, SNORA59A.
- chr1:113,390,515–113,685,923, 1 gene, copy number 8 (within-gene range 1–8): MAGI3.
- chr1:113,576,757–115,698,224, 48 genes, copy number 6–8: MTND5P20, PHTF1, AL133517.1, RSBN1, AL137856.1, PTPN22, AP4B1-AS1, BCL2L15, AP4B1, DCLRE1B, HIPK1-AS1, HIPK1, OLFML3, AL591742.1, SYT6, AL121999.1, MRPL57P1, AL035410.2, TRIM33, AL035410.1, EIF2S2P5, Y_RNA, PKMP1, BCAS2, DENND2C, AMPD1, RN7SL432P, NRAS, CSDE1, RNY1P13, SIKE1, NR1H5P, SYCP1, TSHB, TSPAN2, LINC01765, AL049825.1, NGF-AS1, NGF, AL512638.3, AL512638.1, AL512638.2, ELOCP20, CNOT7P2, AL592436.2, RN7SL420P, AL592436.1, VANGL1.
- chr2:38,814–46,870, 1 gene, copy number 4: FAM110C.
- chr2:52,722,671–71,435,069, 342 genes, copy number 3 (broad region; genes not listed).
- chr2:84,423,528–90,235,370, 211 genes, copy number 3 (broad region; genes not listed).
- chr2:95,434,759–96,039,451, 35 genes, copy number 3–4: AC009238.2, AC009238.1, UBTFL5, AC133104.2, AC133104.1, TRIM43B, AC009237.11, AC009237.1, AC009237.10, AC009237.2, TRIM64FP, AC009237.14, AC009237.3, AC009237.8, AC009237.15, AC009237.5, OR7E102P, TRIM51JP, AC009237.16, AC009237.4, TRIM43, AC009237.7, AC009237.13, AC009237.12, UBTFL3, AC009237.17, AC009237.6, AC009237.9, AC008268.1, GPAT2P1, LINC00342, ANKRD36C, RN7SL210P, FAHD2CP, GPAT2.
- chr2:97,756,333–97,995,948, 3 genes, copy number 4: TMEM131, HMGN1P36, RNU7-96P.
- chr2:242,087,351–242,175,634, 5 genes, copy number 3–4: AC093642.2, LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr3:105,366,909–108,953,879, 46 genes, copy number 3: ALCAM, CBLB, AC079382.1, LINC00882, Y_RNA, AC080097.1, Y_RNA, FCF1P3, MTND4P16, MTND4LP3, MTND3P6, MTCO3P35, MTATP6P22, MTND5P16, MTND6P6, MTCO1P35, MTND1P16, MTND2P14, RNU6-1308P, AC117435.1, AC074043.1, DUBR, AC063944.1, CSP2, AC063944.2, CCDC54, LINC01990, BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2, DZIP3, AC092185.1, RETNLB, TRAT1, GUCA1C.
- chr3:109,602,828–198,123,232, 1,554 genes, copy number 3–4 (broad region; genes not listed).
- chr5:180,784,780–180,839,742, 5 genes, copy number 3 (within-gene range 1–3): MGAT1, AC022413.1, HEIH, LINC00847, AC022413.2.
- chr6:105,919–24,166,374, 366 genes, copy number 3 (broad region; genes not listed).
- chr6:32,934,629–32,981,505, 6 genes, copy number 3–4: HLA-DMB, AL645941.2, HLA-DMA, BRD2, AL645941.1, AL645941.3.
- chr6:62,460,940–63,397,106, 10 genes, copy number 4–5: DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2.
- chr7:63,621,090–63,636,617, 2 genes, copy number 4–6: MIR4283-2, AC006015.1.
- chr7:74,773,962–74,851,551, 2 genes, copy number 3: NCF1, GTF2IRD2.
- chr7:102,345,746–102,356,444, 1 gene, copy number 3: SPDYE6.
- chr8:12,104,389–12,115,516, 1 gene, copy number 9: ZNF705D.
- chr9:136,658,856–136,800,595, 19 genes, copy number 3–9 (within-gene range 1–9): EGFL7, MIR126, AGPAT2, DIPK1B, SNHG7, SNORA17B, SNORA17B, SNORA17A, AL355987.6, AL355987.5, LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3.
- chr9:136,812,788–136,815,536, 1 gene, copy number 3 (within-gene range 2–3): NCLP1.
- chr11:34,853,094–35,420,063, 10 genes, copy number 3 (within-gene range 2–3): APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1.
- chr12:66,950,754–70,434,292, 78 genes, copy number 3 (broad region; genes not listed).
- chr14:61,529,128–61,695,823, 5 genes, copy number 3 (within-gene range 2–3): AL355916.3, AL355916.2, LINC01303, AL355916.1, HIF1A-AS1.
- chr14:67,819,779–68,730,218, 8 genes, copy number 3 (within-gene range 2–3): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3.
- chr14:68,693,656–68,695,734, 1 gene, copy number 3: AL133313.1.
- chr14:104,800,596–104,858,836, 7 genes, copy number 4: ZBTB42, AL590326.1, LINC00638, RPS26P49, RPS2P4, AL583810.2, AL583810.1.
- chr14:104,924,713–104,937,761, 1 gene, copy number 3 (within-gene range 2–3): PLD4.
- chr14:104,985,775–105,021,083, 2 genes, copy number 4: CLBA1, CDCA4.
- chr16:32,388,135–32,436,203, 1 gene, copy number 4: AC138915.2.
- chr16:32,454,612–32,478,250, 3 genes, copy number 3: AC138915.3, AC138915.1, ABCD1P3.
- chr19:1,248,553–1,279,244, 4 genes, copy number 4–5: MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr19:1,392,170–1,435,687, 3 genes, copy number 3–4 (within-gene range 2–4): AC005329.1, GAMT, DAZAP1.
- chr19:38,535,517–38,537,128, 1 gene, copy number 4 (within-gene range 1–4): AC067969.1.
- chr19:50,329,653–50,383,388, 4 genes, copy number 5 (within-gene range 2–5): NR1H2, NAPSB, NAPSA, AC008655.2.
- chr20:1,309,909–1,393,164, 7 genes, copy number 3 (within-gene range 2–3): SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869.
- chr21:34,787,801–36,004,667, 9 genes, copy number 3: RUNX1, AP000331.1, AF015262.1, RPL34P3, EZH2P1, AF015720.1, MIR802, RPS20P1, PPP1R2P2.

Autosomal genes at a single copy (total copy number 1): 30,404. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
